Somatic mutation profile of tumor specimen TCGA-CK-4951-01A (aliquot TCGA-CK-4951-01A-01D-1408-10) from TCGA case TCGA-CK-4951, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.3 years (28,982 days).
Specimen TCGA-CK-4951-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4bf4060-3475-49e6-80d1-bfd19e4be539.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-4951-10A (Blood Derived Normal), aliquot TCGA-CK-4951-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff362b64-ef66-4bc5-8821-0c2a61145dfc

The open-access MAF lists 5,121 somatic variants for this specimen: 3,631 protein-altering or splice-affecting, 1,401 silent, 89 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,049, Silent 1,401, Frame Shift Del 223, Nonsense Mutation 197, Splice Site 58, Splice Region 47, Intron 42, Frame Shift Ins 38, RNA 16, 3'UTR 13, In Frame Del 12, 5'Flank 8.

Variants (750 of 5,121; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557052302, CM105333, CM146246, CM950025, COSV99497603; ClinVar: pathogenic; called by muse, varscan2
- ARSL | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs1085307895, COSV101140565; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCL2L11 | c.466G>A p.G156R (on ENST00000393256 / NM_138621.5; = p.G96R on NM_006538.5) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775080943, COSV58028355, COSV58033623; called by muse, varscan2
- BMPR2 | c.2617C>T p.R873* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as rs137852748, CM002242, COSV65808086; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FERMT1 | c.676del p.Q226Sfs*26 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | catalogued as rs748240859, COSV54090339; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GATA2 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906631, CM109966, COSV62003314, COSV62003787, COSV62005200; ClinVar: likely pathogenic / risk factor / pathogenic; called by muse, mutect2, varscan2
- HSD11B2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs28934592, CM970745, COSV52099104; ClinVar: pathogenic; called by muse, varscan2
- ITGB2 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs137852618, CM990754, COSV56609830, COSV56612029; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LDLR | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.486); catalogued as rs755667663, CM043859, CM055393, COSV52944775, COSV52946049; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MPL | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs751975712, CM110473, COSV65244678; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.969dup p.V324Sfs*8 | Frame Shift Ins (INS) | VAF 48/190 reads (25%) | catalogued as rs587783865; ClinVar: pathogenic; called by mutect2, varscan2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 35/117 reads (30%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- OCA2 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144812594, CM952146; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 36/111 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKD1 | c.7666C>T p.Q2556* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as rs1567184366, CM074425, COSV99238202; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RFX5 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137853099, CM023973, COSV100923880; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- RP1 | c.3843del p.P1282Lfs*12 | Frame Shift Del (DEL) | VAF 40/126 reads (32%) | catalogued as rs769601671; ClinVar: pathogenic; called by mutect2, varscan2
- SH3PXD2B | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267607046, CM101023, COSV100288032; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCB1 | c.406C>T p.Q136* (on ENST00000263121; = p.Q182* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs121434496, COSV99575371; ClinVar: pathogenic; called by muse, varscan2
- SMC1A | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs587784422, COSV59132231; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRIP4 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as rs761865592, CM162648, COSV99974611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WDR19 | c.641dup p.L214Ffs*5 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs587777348; ClinVar: pathogenic; called by mutect2, varscan2
- AAK1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1354922669, COSV68646998; called by muse, varscan2
- AARS1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.099); catalogued as COSV99933525; called by muse, mutect2, varscan2
- AASDHPPT | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as COSV53790792; called by muse, mutect2, varscan2
- AATK | c.2034G>A p.W678* (on ENST00000326724 / NM_001080395.3; = p.W575* on NM_004920.2) | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100352832; called by muse, mutect2
- ABAT | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51625510; called by muse, mutect2, varscan2
- ABCA1 | c.6449C>G p.P2150R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as CM003224, COSV101037006; called by mutect2, varscan2
- ABCA12 | c.4838G>A p.G1613E (on ENST00000272895 / NM_173076.3; = p.G1295E on NM_015657.3) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs745770941, COSV99790118; called by muse, mutect2, varscan2
- ABCA13 | c.14186G>A p.R4729H | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs372286953, COSV68943281; called by muse, mutect2, varscan2
- ABCA2 | c.7192A>T p.N2398Y (on ENST00000614293; = p.N2368Y on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99687703; called by muse, mutect2, varscan2
- ABCA2 | c.6229G>A p.D2077N (on ENST00000614293; = p.D2047N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs370257727; called by muse, mutect2, varscan2
- ABCA2 | c.3898G>A p.D1300N (on ENST00000614293; = p.D1270N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as COSV99687709; called by muse, mutect2, varscan2
- ABCA2 | c.3550G>A p.V1184M (on ENST00000614293; = p.V1154M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376990200; called by muse, mutect2, varscan2
- ABCA2 | c.905A>T p.Q302L (on ENST00000614293; = p.Q272L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.023); catalogued as rs760034490, COSV99687710; called by muse, mutect2, varscan2
- ABCA3 | c.878A>G p.Y293C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100068521; called by muse, mutect2, varscan2
- ABCA4 | c.5662G>A p.V1888M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs960046683, COSV100933131; called by muse, mutect2
- ABCA5 | c.1758A>G p.I586M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs912756380, COSV101201157; called by muse, mutect2, varscan2
- ABCA7 | c.5750G>T p.W1917L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs376845552; called by muse, mutect2, varscan2
- ABCA8 | c.1117A>T p.M373L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV99285852; called by muse, mutect2, varscan2
- ABCB7 | c.376T>C p.S126P (on ENST00000373394 / NM_001271696.3; = p.S127P on NM_004299.6) | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99504391; called by muse, mutect2, varscan2
- ABCB9 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99757743; called by muse, mutect2, varscan2
- ABCC6 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV99228826; called by muse, mutect2, varscan2
- ABCD1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1557052249, COSV99497600; called by muse, mutect2, varscan2
- ABCD1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs781797609, CM050974, COSV99497605; ClinVar: uncertain significance; called by muse, varscan2
- ABCD1 | c.1570T>C p.W524R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM107836, COSV99497609; called by mutect2, varscan2
- ABCG2 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752408502, COSV99419302; called by muse, mutect2, varscan2
- ABHD12 | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.026); catalogued as rs775599343, COSV99405111; called by muse, mutect2, varscan2
- ABHD13 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.401); catalogued as rs751061168, COSV101024171; called by muse, mutect2, varscan2
- ABHD17C | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as COSV99358678; called by muse, mutect2, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | catalogued as rs749606695; called by mutect2, pindel, varscan2
- ABRA | c.756G>T p.W252C | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100357583; called by muse, mutect2, varscan2
- AC097637.1 | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100564530; called by muse, mutect2, varscan2
- AC126283.2 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.039); catalogued as COSV101144460; called by muse, mutect2, varscan2
- AC136428.1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756525278, COSV71169150; called by muse, mutect2, varscan2
- ACAA1 | c.49T>C p.S17P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100086127; called by mutect2, varscan2
- ACAP3 | c.155G>C p.S52T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100686478, COSV61221493; called by muse, mutect2, varscan2
- ACD | c.469G>A p.V157M (on ENST00000620338; = p.V68M on NM_022914.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV54670804; called by muse, mutect2, varscan2
- ACE | c.2885G>A p.W962* | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | catalogued as COSV99327051; called by muse, mutect2, varscan2
- ACIN1 | c.3989G>A p.R1330Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs746023844, COSV99399692; called by muse, mutect2, varscan2
- ACOT7 | c.866T>A p.V289D (on ENST00000377855 / NM_181864.3; = p.V279D on NM_007274.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100830206; called by muse, mutect2, varscan2
- ACOX3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs765806929, COSV100711957; called by muse, mutect2, varscan2
- ACP2 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as rs768932095, COSV99922254; called by muse, mutect2, varscan2
- ACP7 | c.49T>A p.F17I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100488512; called by muse, mutect2, varscan2
- ACSL4 | c.1515C>T p.G505= (on ENST00000340800 / NM_022977.2; = p.G464= on NM_004458.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 44/196 reads (22%) | catalogued as rs779703364, COSV61614853; called by muse, mutect2, varscan2
- ACSL5 | c.1645C>T p.Q549* (on ENST00000354273; = p.Q605* on NM_016234.3) | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100634601, COSV100634614; called by muse, mutect2, varscan2
- ACSS3 | c.1996-1G>A p.X666_splice | Splice Site (SNP) | VAF 18/87 reads (21%) | catalogued as COSV99698881; called by muse, mutect2, varscan2
- ACTB | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV59321652; called by muse, mutect2, varscan2
- ACTB | c.5A>C p.D2A | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.239); catalogued as COSV59321663; called by muse, mutect2, varscan2
- ACTBL2 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs779135503, COSV101379344; called by muse, mutect2, varscan2
- ACTL6B | c.467+1G>A p.X156_splice | Splice Site (SNP) | VAF 14/30 reads (47%) | catalogued as rs1010036956, COSV50514720; called by muse, mutect2, varscan2
- ACTL9 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV100185479; called by muse, mutect2
- ACTN4 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.538); catalogued as rs762475438, COSV99400248; called by muse, mutect2, varscan2
- ACVR1C | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs868070549, COSV54648824; called by muse, mutect2, varscan2
- ADAM21 | c.1831A>G p.T611A | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99961034; called by muse, mutect2, varscan2
- ADAMTS12 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs868273564, COSV100710994; called by muse, mutect2, varscan2
- ADAMTS12 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371132100, COSV61261873; called by muse, mutect2, varscan2
- ADAMTS17 | c.1697G>A p.R566K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs758927075, COSV99170723; called by muse, mutect2, varscan2
- ADAMTS17 | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99170725; called by muse, mutect2, varscan2
- ADAMTS18 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs969622629, COSV51398477; called by muse, mutect2, varscan2
- ADAMTS2 | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302357894, COSV52368069, COSV52381148; called by muse, mutect2, varscan2
- ADAMTS2 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52364352, COSV99282325; called by muse, varscan2
- ADAMTS8 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57298534; called by muse, mutect2, varscan2
- ADAMTS8 | c.871C>A p.R291S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV57298542; called by muse, mutect2, varscan2
- ADAMTSL2 | c.272del p.T91Rfs*126 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as COSV63204569; called by mutect2, pindel, varscan2
- ADAMTSL2 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.772); catalogued as COSV100618968; called by muse, mutect2, varscan2
- ADAMTSL4 | c.148T>C p.W50R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647357; called by muse, varscan2
- ADAMTSL4 | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs769827413, COSV99647361; called by muse, varscan2
- ADAMTSL5 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.131); catalogued as COSV100389164; called by muse, mutect2, varscan2
- ADAMTSL5 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1488114886, COSV100389168; called by muse, mutect2
- ADAP1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99763050; called by muse, varscan2
- ADAR | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.261); catalogued as COSV99426086; called by muse, mutect2, varscan2
- ADARB1 | c.2023C>T p.R675C (on ENST00000360697 / NM_001346687.2; = p.R635C on NM_001112.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs764962336, COSV100653856; called by muse, mutect2, varscan2
- ADCY2 | c.325T>C p.F109L | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100602957; called by muse, varscan2
- ADCY3 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484094256, COSV53170240; called by muse, mutect2, varscan2
- ADCY6 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100326642; called by muse, mutect2, varscan2
- ADCY7 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs754927240, COSV54270471; called by mutect2, varscan2
- ADD1 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99296506; called by muse, mutect2, varscan2
- ADD1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs887730609, COSV99296507; called by muse, mutect2, varscan2
- ADGRA1 | c.1341C>G p.S447R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66927805; called by muse, mutect2, varscan2
- ADGRA2 | c.3005C>T p.T1002M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1359693648, COSV99604936; called by muse, mutect2
- ADGRB1 | c.1409G>A p.W470* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV60103945; called by muse, varscan2
- ADGRB1 | c.2849C>T p.T950M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1159814911, COSV60096398; called by muse, mutect2, varscan2
- ADGRB1 | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1273962372, COSV60103955; called by muse, mutect2, varscan2
- ADGRF3 | c.1237G>A p.A413T (on ENST00000311519 / NM_001145168.1; = p.A214T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100275070; called by muse, mutect2, varscan2
- ADGRG3 | c.1367A>T p.K456M | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100342411; called by muse, mutect2, varscan2
- ADGRG4 | c.7157G>A p.C2386Y | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV99795585; called by muse, mutect2, varscan2
- ADGRL1 | c.583G>A p.D195N (on ENST00000340736 / NM_001008701.3; = p.D190N on NM_014921.5) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs765304593, COSV100529548; called by muse, mutect2, varscan2
- ADGRL2 | c.3493C>A p.Q1165K (on ENST00000370717 / NM_001366005.1; = p.Q1152K on NM_012302.4) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV54692371; called by muse, mutect2, varscan2
- ADGRL2 | c.4131T>A p.N1377K (on ENST00000370717 / NM_001366005.1; = p.N1321K on NM_012302.4) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.949); catalogued as COSV54692384; called by muse, mutect2, varscan2
- ADGRV1 | c.12292T>A p.S4098T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV101316019; called by muse, mutect2, varscan2
- ADM2 | c.406T>A p.S136T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.755); catalogued as COSV99326912; called by muse, mutect2, varscan2
- ADPRS | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV99255533; called by muse, mutect2, varscan2
- ADRB3 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV100799907; called by muse, mutect2, varscan2
- ADSS1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.048); catalogued as COSV100272272; called by muse, mutect2, varscan2
- ADSS1 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100272276; called by muse, mutect2, varscan2
- ADSS2 | c.1151T>A p.I384N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV63696449; called by muse, mutect2, varscan2
- AFAP1L2 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs561584886, COSV100412574; called by muse, mutect2, varscan2
- AFF2 | c.1398-1G>A p.X466_splice | Splice Site (SNP) | VAF 30/137 reads (22%) | catalogued as COSV54009929; called by muse, mutect2, varscan2
- AFF4 | c.2183G>T p.G728V | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99534960; called by muse, mutect2, varscan2
- AGAP2 | c.1838C>T p.P613L (on ENST00000547588 / NM_001122772.2; = p.P277L on NM_014770.4) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1288797141, COSV99223121, COSV99223251; called by muse, mutect2, varscan2
- AGAP4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1289763348, COSV101432651; called by muse, mutect2
- AGBL1 | c.1562C>T p.T521I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV101223172, COSV66857509; called by muse, mutect2, varscan2
- AGO2 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99595130, COSV99595761; called by muse, varscan2
- AGPAT3 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99377470; called by muse, mutect2, varscan2
- AGRN | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV101038874; called by muse, mutect2, varscan2
- AGRN | c.2014G>A p.G672R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs769467600, COSV101038875; called by muse, varscan2
- AGRN | c.3161C>T p.A1054V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs377535426; called by muse, mutect2, varscan2
- AHCTF1 | c.5479G>A p.D1827N (on ENST00000366508; = p.D1801N on NM_015446.5) | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV100403753; called by muse, mutect2, varscan2
- AHDC1 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs370503329; called by muse, varscan2
- AHDC1 | c.350A>T p.N117I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV99899345; called by muse, mutect2, varscan2
- AHI1 | c.1955G>A p.G652D | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55637247; called by muse, mutect2, varscan2
- AHNAK | c.4658T>G p.V1553G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV99947640; called by muse, mutect2, varscan2
- AHNAK2 | c.14779G>A p.A4927T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.073); catalogued as COSV60932886; called by muse, mutect2, varscan2
- AHNAK2 | c.12460G>A p.A4154T | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV60932895; called by muse, mutect2, varscan2
- AHNAK2 | c.2892G>A p.M964I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs536326287, COSV60932928; called by muse, mutect2, varscan2
- AHNAK2 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs565473345, COSV60932935; called by muse, mutect2, varscan2
- AHRR | c.709-1G>A p.X237_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100327341; called by muse, mutect2, varscan2
- AK9 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs369829767, COSV99572560; called by muse, mutect2, varscan2
- AKAP13 | c.6293G>A p.G2098D (on ENST00000394518 / NM_007200.5; = p.G2102D on NM_006738.6) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1019909689, COSV100773841; called by muse, mutect2, varscan2
- AKAP6 | c.5026A>T p.I1676L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs973296297, COSV99801112; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 52/154 reads (34%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP8 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs1305262102, COSV54101116; called by muse, mutect2, varscan2
- AKNAD1 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV62204364; called by muse, mutect2, varscan2
- AKR1B1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1229108905, COSV53646458; called by muse, mutect2, varscan2
- AKT1 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as rs1302148730, COSV100838131; called by muse, mutect2
- AL662899.2 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100789014; called by muse, mutect2, varscan2
- ALDH18A1 | c.1277T>A p.L426* | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | catalogued as COSV100973178; called by muse, mutect2, varscan2
- ALDH18A1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs1320690165, COSV100973180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1A3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100320434; called by muse, mutect2, varscan2
- ALDH2 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55672169; called by muse, mutect2, varscan2
- ALDOC | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs775893117, COSV52026365; called by muse, mutect2, varscan2
- ALG11 | c.52del p.Y18Ifs*35 | Frame Shift Del (DEL) | VAF 49/186 reads (26%) | catalogued as COSV73000541; called by mutect2, pindel, varscan2
- ALKBH2 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99980394; called by muse, mutect2, varscan2
- ALLC | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as rs375032704; called by muse, mutect2, varscan2
- ALOX5 | c.1622C>A p.T541N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100980073; called by muse, mutect2, varscan2
- ALPK3 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.058); catalogued as rs115195927, COSV51937611, COSV99360974; ClinVar: uncertain significance; called by mutect2, varscan2
- ALPK3 | c.4322C>T p.T1441M | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs141398841; called by muse, mutect2, varscan2
- ALS2 | c.3011T>C p.V1004A | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99969325; called by muse, mutect2, varscan2
- ALS2 | c.2911G>A p.V971M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV99969326; called by muse, mutect2, varscan2
- AMBRA1 | c.3210-1G>A p.X1070_splice (on ENST00000458649 / NM_001367468.1; = p.X980_splice on NM_017749.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100094050; called by muse, mutect2
- AMBRA1 | c.2182G>A p.A728T (on ENST00000458649 / NM_001367468.1; = p.A638T on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1489326861, COSV100094057; called by muse, mutect2, varscan2
- AMIGO3 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1361515145, COSV100246593; called by muse, varscan2
- AMIGO3 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs778705981, COSV100246596; called by muse, varscan2
- AMOTL1 | c.697A>G p.R233G | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV100133794; called by muse, mutect2, varscan2
- AMPD1 | c.2113T>C p.F705L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100815045; called by muse, mutect2, varscan2
- AMY2B | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 132/482 reads (27%) | catalogued as rs761465185, COSV63717172; called by muse, mutect2, varscan2
- ANAPC2 | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV59245523; called by muse, mutect2, varscan2
- ANAPC7 | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV101482859; called by muse, mutect2, varscan2
- ANGEL1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs752001734, COSV51872837; called by muse, mutect2, varscan2
- ANK3 | c.11707A>G p.T3903A | Missense Mutation (SNP) | VAF 118/411 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99780120; called by muse, mutect2, varscan2
- ANKAR | c.961T>C p.F321L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV55618846; called by muse, mutect2, varscan2
- ANKAR | c.4193T>A p.F1398Y | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.396); catalogued as COSV51464102; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6706C>G p.R2236G | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV99783412; called by muse, mutect2, varscan2
- ANKK1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100392870; called by muse, mutect2
- ANKLE2 | c.1303C>A p.H435N | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100514138; called by muse, mutect2, varscan2
- ANKRD1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs730880050, COSV100865336; ClinVar: uncertain significance; called by muse, varscan2
- ANKRD11 | c.7313A>T p.Y2438F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99969411; called by muse, mutect2, varscan2
- ANKRD13A | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs894655291, COSV99923987; called by muse, mutect2, varscan2
- ANKRD13B | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762020530, COSV100801238; called by muse, mutect2, varscan2
- ANKRD17 | c.2601G>T p.E867D | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV100429257; called by muse, mutect2, varscan2
- ANKRD2 | c.270G>A p.K90= | Splice Region (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100080868; called by muse, mutect2
- ANKRD27 | c.1530C>A p.S510R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as COSV100042835; called by mutect2, varscan2
- ANKRD35 | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1553738984, COSV62910767, COSV62911184; called by mutect2, varscan2
- ANKRD35 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100841743; called by muse, mutect2, varscan2
- ANKRD52 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs772113165, COSV99921323; called by muse, mutect2, varscan2
- ANO5 | c.1750G>T p.G584C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100201878; called by muse, mutect2, varscan2
- ANO5 | c.1954T>A p.Y652N | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100201880; called by muse, mutect2, varscan2
- ANO8 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1290611609, COSV99344507; called by muse, mutect2, varscan2
- ANO8 | c.667T>C p.S223P | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV99344511; called by muse, mutect2, varscan2
- ANP32A | c.207T>C p.L69= | Splice Region (SNP) | VAF 23/84 reads (27%) | catalogued as COSV99143028; called by muse, mutect2, varscan2
- ANTXR1 | c.1278A>T p.E426D | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV100362538; called by muse, mutect2, varscan2
- ANXA13 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs112185912, COSV99146133; called by muse, mutect2, varscan2
- ANXA13 | c.713C>G p.T238S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99146135; called by muse, mutect2, varscan2
- ANXA6 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62908662; called by muse, mutect2, varscan2
- AOAH | c.1599G>A p.E533= | Splice Region (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99332878; called by muse, mutect2, varscan2
- AP001458.2 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1049860625, COSV57951662; called by muse, mutect2, varscan2
- AP1B1 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV100434608; called by muse, mutect2, varscan2
- AP2A1 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs764249348, COSV99883311; called by muse, varscan2
- AP2A1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1315493907, COSV100756276; called by muse, mutect2, varscan2
- AP3D1 | c.3092C>T p.A1031V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs370612433; called by muse, mutect2, varscan2
- AP3D1 | c.3070A>T p.I1024F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.856); catalogued as COSV100642706; called by muse, varscan2
- AP3D1 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as rs758018772, COSV61427494; called by muse, mutect2, varscan2
- APAF1 | c.2978A>T p.N993I (on ENST00000551964 / NM_181861.2; = p.N939I on NM_001160.3) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV100244113; called by muse, mutect2, varscan2
- APBA1 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV55231195; called by muse, mutect2, varscan2
- APBA2 | c.1778C>A p.P593H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101258165; called by muse, mutect2, varscan2
- APBB3 | c.779A>T p.D260V (on ENST00000357560 / NM_133173.2; = p.D267V on NM_006051.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV100021313; called by muse, mutect2, varscan2
- APC2 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52022603; called by muse, mutect2, varscan2
- APEH | c.1441G>A p.G481S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV56537179; called by muse, mutect2, varscan2
- APOA4 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as COSV100759324; called by muse, mutect2, varscan2
- APOD | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV100581196; called by muse, mutect2, varscan2
- AQP1 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV61268338; called by muse, mutect2, varscan2
- AQP2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs995684800, CM024086, COSV52232198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARAP2 | c.3672del p.K1224Nfs*17 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as COSV58291165; called by mutect2, pindel, varscan2
- ARFGAP1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs763879486, COSV62262698; called by muse, mutect2, varscan2
- ARFGEF1 | c.4529T>C p.L1510P | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.786); catalogued as COSV99141005; called by muse, mutect2, varscan2
- ARFGEF2 | c.1601T>A p.V534E | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100904267; called by muse, mutect2, varscan2
- ARFGEF2 | c.2258A>G p.Y753C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100904268; called by muse, mutect2, varscan2
- ARFGEF3 | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as rs373609636, COSV52471669; called by muse, mutect2, varscan2
- ARFGEF3 | c.4841C>T p.A1614V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs767280503, COSV52453788; called by muse, mutect2, varscan2
- ARHGAP11A | c.1232G>A p.C411Y | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100853253; called by muse, mutect2, varscan2
- ARHGAP21 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs372140665, COSV57607813; called by muse, mutect2, varscan2
- ARHGAP22 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV99985310; called by muse, mutect2, varscan2
- ARHGAP27 | c.2539G>T p.A847S (on ENST00000428638 / NM_001282290.1; = p.A506S on NM_199282.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100976531; called by muse, mutect2, varscan2
- ARHGAP27 | c.1747C>T p.R583W (on ENST00000428638 / NM_001282290.1; = p.R242W on NM_199282.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368752990; called by muse, mutect2, varscan2
- ARHGAP29 | c.2519A>T p.K840I | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV99558230; called by muse, mutect2, varscan2
- ARHGAP30 | c.3211A>G p.R1071G (on ENST00000368013 / NM_001025598.2; = p.R860G on NM_181720.3) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV100920278; called by muse, mutect2, varscan2
- ARHGAP33 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs766751884, COSV99138475; called by muse, mutect2, varscan2
- ARHGAP33 | c.1283T>C p.V428A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV99138478; called by muse, mutect2, varscan2
- ARHGAP36 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs866987298, COSV99357740; called by muse, mutect2, varscan2
- ARHGAP4 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100604066; called by muse, mutect2, varscan2
- ARHGAP45 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as COSV100490733; called by muse, mutect2, varscan2
- ARHGAP45 | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV57429023; called by muse, mutect2, varscan2
- ARHGAP5 | c.1614G>T p.R538S | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565413, COSV61536336; called by muse, mutect2, varscan2
- ARHGAP6 | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.31); catalogued as rs780455582, COSV100272908, COSV57290778; called by muse, mutect2, varscan2
- ARHGDIA | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99482578, COSV99482583; called by muse, mutect2, varscan2
- ARHGEF1 | c.1523T>A p.F508Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100529030; called by muse, mutect2, varscan2
- ARHGEF16 | c.1023-1G>A p.X341_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | catalogued as COSV65683443; called by muse, mutect2, varscan2
- ARHGEF17 | c.1567C>A p.P523T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV99735681; called by muse, mutect2, varscan2
- ARHGEF2 | c.2654G>A p.R885H (on ENST00000361247 / NM_001162383.2; = p.R857H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs377007664; called by mutect2, varscan2
- ARHGEF2 | c.1766A>T p.Y589F (on ENST00000361247 / NM_001162383.2; = p.Y561F on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV100560630; called by muse, mutect2, varscan2
- ARHGEF25 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs761488499, COSV99677988; called by muse, mutect2, varscan2
- ARHGEF3 | c.38A>C p.K13T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as rs3732507, COSV99575401; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID1B | c.4268G>A p.G1423E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV51683749; called by muse, mutect2, varscan2
- ARIH2 | c.962-1G>A p.X321_splice | Splice Site (SNP) | VAF 12/32 reads (38%) | catalogued as rs202082295, COSV100711328; called by muse, mutect2, varscan2
- ARL10 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372502997; called by muse, mutect2
- ARMC2 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.293); catalogued as COSV100933562; called by muse, mutect2, varscan2
- ARMC8 | c.1078G>A p.A360T (on ENST00000469044 / NM_001363941.2; = p.A346T on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV100627656; called by muse, mutect2, varscan2
- ARNT2 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100309062; called by muse, mutect2, varscan2
- ARNTL2 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as rs11049005; called by muse, mutect2, varscan2
- ARSA | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV53351468; called by muse, mutect2, varscan2
- ARSG | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs769238862, COSV100048418; called by muse, mutect2, varscan2
- ARSI | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs1472402772, COSV60817441; called by muse, mutect2, varscan2
- ART1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as COSV51707577; called by muse, mutect2, varscan2
- ASB15 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216642394, COSV99306574; called by muse, mutect2, varscan2
- ASB2 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100279362; called by muse, varscan2
- ASB4 | c.1108dup p.Y370Lfs*10 | Frame Shift Ins (INS) | VAF 38/154 reads (25%) | catalogued as rs1446029621; called by mutect2, pindel, varscan2
- ASCC1 | c.991A>G p.K331E (on ENST00000342444 / NM_001369085.1; = p.K303E on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as COSV57729393; called by muse, mutect2, varscan2
- ASF1B | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs932919750, COSV54617127; called by muse, mutect2, varscan2
- ASNSD1 | c.717A>C p.K239N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV99641194; called by muse, mutect2, varscan2
- ASRGL1 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV100077885; called by muse, mutect2, varscan2
- ASTN1 | c.1417C>T p.H473Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV99921805; called by muse, mutect2, varscan2
- ASTN2 | c.2461G>A p.V821M (on ENST00000313400 / NM_001365069.1; = p.V770M on NM_014010.5) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1005460121, COSV100527674; called by muse, mutect2, varscan2
- ASXL1 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201016007, COSV100039353; called by muse, mutect2, varscan2
- ASXL1 | c.1708C>A p.P570T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100039356; called by muse, mutect2
- ATF7 | c.517T>A p.Y173N (on ENST00000548446 / NM_001366555.2; = p.Y162N on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV60646780; called by muse, mutect2, varscan2
- ATF7IP | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV99661702; called by muse, mutect2, varscan2
- ATG2A | c.5747G>A p.R1916H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770497554, COSV63475508; called by muse, mutect2, varscan2
- ATG2A | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV101034408; called by muse, mutect2
- ATG3 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as rs1044323319, COSV51928264; called by muse, mutect2, varscan2
- ATG9B | c.27del p.R10Efs*96 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs760721903; called by mutect2, varscan2
- ATOH1 | c.311A>G p.E104G | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1483640289, COSV100024519; called by muse, mutect2, varscan2
- ATP11A | c.2971A>G p.T991A | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52126109; called by muse, mutect2, varscan2
- ATP11B | c.874A>T p.I292F | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV100017796; called by muse, mutect2
- ATP12A | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs565225438, COSV54516010; called by muse, mutect2
- ATP1A1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99814498; called by muse, mutect2, varscan2
- ATP1A3 | c.1829G>A p.R610H (on ENST00000545399 / NM_001256214.2; = p.R597H on NM_152296.5) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100132236; called by muse, mutect2, varscan2
- ATP1A4 | c.197A>T p.D66V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV100927559; called by muse, mutect2, varscan2
- ATP2A3 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99989161; called by muse, mutect2, varscan2
- ATP2B2 | c.1828C>A p.R610S (on ENST00000352432; = p.R576S on NM_001683.5) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100659980, COSV59498430; called by muse, mutect2, varscan2
- ATP2B2 | c.682T>C p.F228L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100659981; called by muse, mutect2, varscan2
- ATP2C1 | c.2212A>G p.N738D | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100146721; called by muse, mutect2, varscan2
- ATP4B | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs533455765, COSV100089746; called by muse, mutect2, varscan2
- ATP5F1B | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV100008121; called by muse, mutect2, varscan2
- ATP7B | c.3106G>A p.V1036I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as rs761147984, CM087673, COSV54438958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8A2 | c.1768T>C p.Y590H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99682101; called by muse, varscan2
- ATP8B1 | c.3491G>A p.R1164Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs778359776, COSV99377305; called by muse, mutect2, varscan2
- ATP8B2 | c.146C>T p.A49V (on ENST00000672630; = p.A16V on NM_001005855.2) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368910102; called by muse, mutect2, varscan2
- ATP8B4 | c.1406G>T p.R469M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99465648; called by muse, mutect2, varscan2
- ATP9B | c.3317T>A p.F1106Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV100303624; called by muse, mutect2, varscan2
- ATRNL1 | c.3578A>C p.K1193T | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV100370805; called by muse, mutect2
- ATXN2 | c.3209T>C p.I1070T (on ENST00000550104; = p.I910T on NM_002973.4) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV101112772; called by muse, mutect2, varscan2
- AURKB | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60246318; called by muse, mutect2, varscan2
- AVL9 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100594643; called by muse, mutect2, varscan2
- AVL9 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV100594646; called by muse, mutect2, varscan2
- AVPI1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs941243490, COSV101033309; called by muse, mutect2, varscan2
- B3GALT4 | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV101005636; called by muse, mutect2, varscan2
- B3GNT6 | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100845787; called by muse, mutect2, varscan2
- B3GNT9 | c.971A>T p.Q324L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.102); catalogued as COSV54629668; called by muse, mutect2, varscan2
- B4GALNT1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100247170; called by muse, mutect2, varscan2
- B4GAT1 | c.320T>A p.L107Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as COSV60820871; called by muse, mutect2, varscan2
- BAAT | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV99408499; called by muse, mutect2, varscan2
- BAHCC1 | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV57034249; called by muse, mutect2, varscan2
- BAHCC1 | c.4814G>A p.R1605H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs370431109; called by muse, varscan2
- BAHCC1 | c.4918G>A p.A1640T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs782778492, COSV57034266; called by muse, varscan2
- BAHCC1 | c.6869G>T p.R2290L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57034295; called by muse, mutect2, varscan2
- BAHCC1 | c.7019G>C p.R2340P | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100311635, COSV100311683; called by muse, mutect2, varscan2
- BAHD1 | c.1713G>C p.K571N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as COSV101346759; called by muse, varscan2
- BAIAP2L2 | c.1031T>A p.L344Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101091967; called by muse, mutect2
- BAP1 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99964014; called by muse, mutect2, varscan2
- BAP1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.027); catalogued as COSV56238890; called by muse, mutect2, varscan2
- BARHL1 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.653); catalogued as COSV99707588; called by muse, mutect2, varscan2
- BBS7 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); catalogued as rs771957843, COSV99144946; called by muse, mutect2, varscan2
- BCAN | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761822025, COSV100228125; called by muse, mutect2, varscan2
- BCAN | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.396); catalogued as rs1374965645, COSV100228127, COSV61258548; called by muse, mutect2, varscan2
- BCAR1 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50785033; called by muse, mutect2, varscan2
- BCAR1 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs746131932, COSV99366048; called by muse, mutect2, varscan2
- BCAR1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs747374409, COSV99366683; called by muse, mutect2, varscan2
- BCAS3 | c.2653G>A p.G885R (on ENST00000390652 / NM_001353144.2; = p.G870R on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as COSV101175974; called by muse, mutect2, varscan2
- BCKDK | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs755584594, COSV54891042; called by muse, mutect2, varscan2
- BCL2L10 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99548571; called by muse, mutect2, varscan2
- BCL3 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1004862507, COSV99378175; called by muse, varscan2
- BCL6 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV99215741; called by muse, mutect2, varscan2
- BCL7C | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99288614; called by muse, mutect2, varscan2
- BCL9 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV52343167, COSV52347744; called by muse, mutect2, varscan2
- BCL9 | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99325186; called by muse, mutect2, varscan2
- BCL9 | c.3025A>G p.M1009V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99325189; called by muse, mutect2, varscan2
- BCLAF1 | c.836A>T p.N279I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62146354; called by muse, mutect2, varscan2
- BCOR | c.4949A>T p.Y1650F (on ENST00000378444 / NM_001123385.2; = p.Y1616F on NM_017745.6) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs371469926, COSV100653351; called by muse, varscan2
- BCOR | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs143744110, COSV60708679; called by muse, mutect2, varscan2
- BEND3 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs782458566, COSV64680151; called by muse, mutect2, varscan2
- BEND7 | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 53/176 reads (30%) | PolyPhen benign (0.001); catalogued as rs768612275, COSV100346730; called by muse, mutect2, varscan2
- BEST1 | c.1352A>T p.D451V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV99861318; called by muse, mutect2, varscan2
- BEST2 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99244428; called by muse, mutect2, varscan2
- BGN | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV100525194; called by muse, mutect2, varscan2
- BICD2 | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100794117; called by muse, mutect2, varscan2
- BICDL1 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV101287342; called by muse, mutect2
- BIRC3 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs1431281475, COSV54820267; called by muse, varscan2
- BIRC3 | c.635T>C p.L212S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54820278; called by muse, mutect2
- BLK | c.881A>C p.E294A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV99377225; called by muse, mutect2, varscan2
- BMF | c.257G>A p.C86Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1488564127, COSV55019720; called by muse, mutect2, varscan2
- BMP2K | c.3244C>T p.H1082Y | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99785132; called by muse, mutect2, varscan2
- BMPER | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as rs773516778, COSV51816721; called by muse, mutect2, varscan2
- BMS1 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs745427494, COSV65735518; called by muse, mutect2, varscan2
- BNC2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as rs1281294007, COSV101032997; called by muse, mutect2, varscan2
- BNIP5 | c.1022T>A p.I341N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.329); catalogued as COSV71325891; called by muse, mutect2, varscan2
- BOLA1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100975405; called by muse, mutect2, varscan2
- BPIFB6 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs145056603; called by muse, mutect2, varscan2
- BRAF | c.1328dup p.A444Cfs*9 (on ENST00000288602 / NM_001374244.1; = p.A404Cfs*9 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | catalogued as rs777474487; called by mutect2, varscan2
- BRD1 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1569111051, COSV53462240; called by muse, mutect2, varscan2
- BRD1 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV53456078, COSV99349814; called by muse, mutect2, varscan2
- BRD3 | c.337T>A p.Y113N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100325106, COSV104409696; called by muse, mutect2, varscan2
- BRF1 | c.748A>T p.I250F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100527349; called by muse, mutect2, varscan2
- BRMS1 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as rs1159239724, COSV100240205; called by muse, mutect2, varscan2
- BRPF1 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57404107, COSV57405444; called by muse, mutect2, varscan2
- BRPF3 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763603141, COSV100325891; called by muse, mutect2, varscan2
- BRPF3 | c.2561del p.P854Rfs*6 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs1413008697, COSV60208966; called by mutect2, pindel, varscan2
- BRSK2 | c.128A>G p.Q43R | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV57549949; called by muse, mutect2, varscan2
- BRWD1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100313452; called by muse, mutect2
- BSG | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as COSV100344785; called by muse, mutect2, varscan2
- BSN | c.3208A>G p.T1070A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV99608560; called by muse, mutect2, varscan2
- BSN | c.9436C>T p.R3146C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs201112949, COSV99608565; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTBD2 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55310306, COSV99724771; called by muse, mutect2, varscan2
- BTD | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100329601; called by muse, mutect2, varscan2
- BTN3A2 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.368); catalogued as COSV100709656; called by muse, mutect2, varscan2
- BTRC | c.1528C>T p.R510C (on ENST00000370187 / NM_033637.4; = p.R474C on NM_003939.5) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64579491; called by muse, mutect2, varscan2
- BUB1 | c.365T>A p.L122H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs537793951, COSV100241281; called by muse, mutect2, varscan2
- BYSL | c.1134G>A p.W378* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV57828639; called by muse, mutect2, varscan2
- C10orf120 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1431253930, COSV61491778, COSV61492642; called by muse, mutect2, varscan2
- C12orf65 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs930288422, COSV99473953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C19orf44 | c.1478G>A p.R493K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.52); catalogued as rs908826916, COSV99685204; called by muse, mutect2, varscan2
- C19orf73 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.803); catalogued as COSV99674473; called by muse, mutect2, varscan2
- C1QL1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.669); catalogued as COSV99492758; called by muse, varscan2
- C1QL3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV54348460; called by muse, mutect2, varscan2
- C1QTNF1 | c.531C>G p.H177Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as COSV100189959; called by muse, mutect2, varscan2
- C1orf216 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs769788509, COSV99230954; called by muse, mutect2, varscan2
- C21orf58 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as rs373559696; called by muse, mutect2, varscan2
- C22orf15 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs946576566, COSV100533646; called by muse, mutect2, varscan2
- C2CD5 | c.178-2A>T p.X60_splice | Splice Site (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100448773; called by muse, mutect2, varscan2
- C2CD5 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100448774; called by muse, mutect2, varscan2
- C4A | c.3604C>G p.L1202V | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101418338, COSV71179346; called by muse, mutect2, varscan2
- C5AR2 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs150108068, COSV57256464; called by muse, mutect2, varscan2
- C5orf15 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV99198324; called by muse, mutect2, varscan2
- C6orf15 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs142530210; called by muse, mutect2, varscan2
- C8orf74 | c.873G>T p.K291N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100261978; called by muse, mutect2, varscan2
- C9orf131 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.129); catalogued as rs750913813, COSV100398117; called by muse, mutect2, varscan2
- C9orf135 | c.596T>C p.I199T | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.656); catalogued as COSV65877052; called by muse, mutect2, varscan2
- CABIN1 | c.3970C>T p.H1324Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.469); catalogued as COSV99573272; called by muse, mutect2, varscan2
- CABIN1 | c.4934G>A p.R1645H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99573275; called by muse, mutect2, varscan2
- CABIN1 | c.5371G>A p.E1791K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.038); catalogued as rs201053897, COSV99573276; called by muse, mutect2, varscan2
- CABLES1 | c.904G>A p.A302T (on ENST00000256925 / NM_001100619.2; = p.A37T on NM_138375.2) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs917354944, COSV56934757; called by muse, mutect2, varscan2
- CACHD1 | c.2101G>A p.V701I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.846); catalogued as COSV99262361; called by muse, mutect2, varscan2
- CACNA1A | c.2421G>A p.W807* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV64203761; called by muse, mutect2, varscan2
- CACNA1A | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV64214057; called by muse, mutect2, varscan2
- CACNA1C | c.4157C>T p.A1386V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100219202; called by muse, mutect2, varscan2
- CACNA1F | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs782280160, COSV59904568; called by muse, mutect2, varscan2
- CACNA1G | c.3331A>T p.N1111Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV61741277; called by muse, mutect2, varscan2
- CACNA1H | c.6031C>T p.R2011W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs753241781, COSV99326742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D2 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56569947; called by muse, mutect2, varscan2
- CACNB1 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748883383, COSV100703427; called by muse, mutect2, varscan2
- CACNG7 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1173224176, COSV55816209, COSV99712051; called by muse, varscan2
- CADM4 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV99731545; called by muse, mutect2, varscan2
- CADPS | c.1884G>T p.K628N | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99338449; called by muse, mutect2, varscan2
- CADPS2 | c.2834C>T p.S945F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV100463023; called by muse, mutect2, varscan2
- CALHM5 | c.891G>C p.E297D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV100635603, COSV62067808; called by muse, mutect2
- CALR | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.228); catalogued as COSV100330741; called by muse, mutect2, varscan2
- CAMSAP1 | c.3008C>T p.S1003F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs891237284, COSV100409882; called by muse, mutect2, varscan2
- CAMSAP3 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99350786; called by muse, mutect2, varscan2
- CAMTA2 | c.2528C>T p.S843L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs750393389, COSV99236537; called by muse, mutect2, varscan2
- CAMTA2 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100772623; called by muse, mutect2, varscan2
- CAPN15 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748393081, COSV99562471; called by muse, mutect2, varscan2
- CAPN15 | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99562472; called by muse, mutect2
- CAPN15 | c.3012C>G p.C1004W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99562476; called by muse, varscan2
- CAPN5 | c.1433G>A p.R478H (on ENST00000456580; = p.R438H on NM_004055.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782109539, COSV53687510; called by muse, mutect2, varscan2
- CARD10 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as rs762039457, COSV99324983; called by muse, mutect2, varscan2
- CARD11 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100712240; called by muse, mutect2, varscan2
- CARD6 | c.2512A>G p.T838A | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765490996, COSV99620825; called by muse, mutect2, varscan2
- CARMIL3 | c.3314C>T p.S1105F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV100549613, COSV57728363; called by muse, mutect2, varscan2
- CASKIN1 | c.4205C>T p.S1402L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs779842332, COSV100399547; called by muse, mutect2, varscan2
- CASKIN1 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.472); catalogued as COSV100624113; called by muse, mutect2, varscan2
- CASKIN2 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100395394; called by muse, mutect2, varscan2
- CASP9 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.265); catalogued as rs759311957; called by muse, mutect2, varscan2
- CATSPER1 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100375978, COSV56411682; called by muse, mutect2, varscan2
- CATSPERG | c.2402T>A p.L801Q | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99286539; called by muse, mutect2, varscan2
- CBR3 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV51742526; called by muse, mutect2, varscan2
- CBX1 | c.165A>T p.E55D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99848151; called by muse, mutect2, varscan2
- CBX2 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as COSV99490882; called by muse, mutect2, varscan2
- CBX2 | c.1386G>T p.E462D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV53968999, COSV99490883; called by muse, mutect2, varscan2
- CBX5 | c.423A>G p.K141= | Splice Region (SNP) | VAF 17/56 reads (30%) | catalogued as rs1231614863, COSV52939119; called by muse, mutect2, varscan2
- CBX8 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs757406974, COSV99485881; called by muse, mutect2, varscan2
- CBY2 | c.199A>T p.S67C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV100137616; called by muse, mutect2, varscan2
- CC2D1A | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100528491; called by muse, mutect2, varscan2
- CC2D1B | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750715210, COSV99430002; called by muse, mutect2, varscan2
- CCAR1 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs779871042, COSV56275245; called by muse, mutect2, varscan2
- CCDC102B | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.011); catalogued as rs752284624, COSV60147784; called by muse, mutect2, varscan2
- CCDC105 | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs751365016, COSV52964237; called by muse, mutect2, varscan2
- CCDC106 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100454266; called by muse, mutect2, varscan2
- CCDC107 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.741); catalogued as COSV100526242; called by muse, mutect2, varscan2
- CCDC116 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs762931042, COSV99488925; called by muse, mutect2, varscan2
- CCDC120 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100900636; called by muse, varscan2
- CCDC130 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.136); catalogued as rs945976002, COSV99237510; called by muse, varscan2
- CCDC138 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.414); catalogued as COSV54572438; called by muse, mutect2, varscan2
- CCDC142 | c.1607G>A p.R536H (on ENST00000393965 / NM_001365575.2; = p.R529H on NM_032779.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs761087638, COSV99252138; called by mutect2, varscan2
- CCDC150 | c.2222C>G p.A741G | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.337); catalogued as COSV55874634, COSV99776969; called by muse, mutect2, varscan2
- CCDC40 | c.2527C>T p.L843F | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV66479153; called by muse, mutect2, varscan2
- CCDC62 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53437595; called by muse, varscan2
- CCDC8 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.211); catalogued as rs769881544, COSV100282042; called by mutect2, varscan2
- CCDC87 | c.2506C>A p.P836T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.039); catalogued as rs1436691326, COSV100040003, COSV59578558; called by muse, mutect2, varscan2
- CCDC88C | c.5191C>T p.P1731S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV57798354; called by muse, mutect2, varscan2
- CCDC88C | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV66232959; called by muse, mutect2, varscan2
- CCDC96 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.52); catalogued as rs761560311, COSV59509760; called by muse, mutect2
- CCL14 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs754659661; called by muse, mutect2, varscan2
- CCM2L | c.141dup p.D48Rfs*12 | Frame Shift Ins (INS) | VAF 22/64 reads (34%) | catalogued as rs769673764; called by mutect2, pindel, varscan2
- CCM2L | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs138375629; called by mutect2, varscan2
- CCN6 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100037052; called by muse, mutect2, varscan2
- CCNA1 | c.759G>T p.E253D | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs1444021980, COSV99714601; called by muse, mutect2, varscan2
- CCNF | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV53543735; called by muse, mutect2, varscan2
- CCNJ | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); catalogued as COSV99796254; called by muse, mutect2, varscan2
- CCNL2 | c.536C>G p.A179G | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV68766994, COSV68767207; called by muse, mutect2, varscan2
- CCR10 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs962918536, COSV99226460; called by muse, varscan2
- CCR10 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV52848361, COSV99226462; called by muse, mutect2, varscan2
- CCR4 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58384381; called by muse, mutect2, varscan2
- CCSER2 | c.1229T>C p.L410S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99825980; called by muse, mutect2, varscan2
- CCZ1B | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs373823879; called by muse, mutect2, varscan2
- CD163 | c.2377T>A p.S793T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.676); catalogued as COSV100775856; called by muse, mutect2, varscan2
- CD19 | c.1654G>T p.G552C (on ENST00000324662 / NM_001178098.2; = p.G551C on NM_001770.6) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100218138; called by muse, mutect2, varscan2
- CD248 | c.2026C>T p.L676F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs773387758, COSV100256606; called by muse, mutect2, varscan2
- CD276 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs751833994, COSV59203973; called by muse, mutect2, varscan2
- CD2BP2 | c.136T>A p.S46T | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV99977104; called by muse, mutect2, varscan2
- CD300LG | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as COSV53226093; called by muse, mutect2, varscan2
- CD38 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.279); catalogued as COSV99882725; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD6 | c.1606C>T p.H536Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.129); catalogued as COSV57841542, COSV57843263; called by muse, varscan2
- CD7 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100444876; called by muse, mutect2, varscan2
- CD70 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55566616; called by muse, mutect2, varscan2
- CDAN1 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV100661323; called by muse, mutect2, varscan2
- CDAN1 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs375652610; called by muse, mutect2, varscan2
- CDC25A | c.442T>C p.F148L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100207483; called by muse, mutect2, varscan2
- CDC34 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); catalogued as rs774925566, COSV99198837; called by muse, mutect2, varscan2
- CDC42BPB | c.3428C>T p.A1143V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1277468665, COSV100775458; called by muse, mutect2, varscan2
- CDC42BPG | c.2629G>A p.G877S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs1308769006, COSV100712075; called by muse, mutect2, varscan2
- CDC42BPG | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs749921349, COSV100712076; called by muse, mutect2, varscan2
- CDCP1 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV56104899; called by muse, mutect2, varscan2
- CDH11 | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV99218500; called by muse, mutect2, varscan2
- CDH19 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50954317; called by muse, mutect2, varscan2
- CDH22 | c.2375C>T p.S792L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs897701034, COSV100952863; called by muse, mutect2
- CDH4 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs370608791, COSV100849381; called by muse, mutect2, varscan2
- CDIP1 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99566567; called by muse, mutect2, varscan2
- CDK10 | c.320G>A p.G107E (on ENST00000353379 / NM_052988.5; = p.G36E on NM_052987.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99232321; called by muse, mutect2, varscan2
- CDK11A | c.362G>A p.R121H (on ENST00000378633 / NM_001313896.2; = p.R131H on NM_024011.4) | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen probably damaging (0.998); catalogued as rs766098874, COSV62267075; called by muse, mutect2, varscan2
- CDK12 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV101420459; called by muse, varscan2
- CDK12 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.928); catalogued as rs147398865; called by muse, varscan2
- CDK12 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV70999175; called by muse, mutect2, varscan2
- CDK12 | c.2435T>A p.V812E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101420461; called by muse, varscan2
- CDK12 | c.2994C>A p.D998E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV101420462; called by muse, mutect2, varscan2
- CDKL2 | c.1020G>A p.Q340= | Splice Region (SNP) | VAF 44/123 reads (36%) | catalogued as COSV100276965, COSV100277110; called by muse, mutect2, varscan2
- CDKN1A | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as COSV55189290; called by muse, mutect2
- CDON | c.3524G>A p.S1175N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as rs1332731475, COSV99701409; called by muse, mutect2, varscan2
- CEACAM3 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 76/231 reads (33%) | catalogued as COSV55763444; called by muse, mutect2, varscan2
- CECR2 | c.782G>A p.R261H (on ENST00000342247 / NM_001290047.2; = p.R98H on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760539949, COSV52835916; called by muse, mutect2
- CECR2 | c.1693G>A p.A565T (on ENST00000342247 / NM_001290047.2; = p.A382T on NM_001290046.1) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99378037; called by muse, mutect2, varscan2
- CELA2B | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as rs751797790, COSV65546054; called by muse, mutect2, varscan2
- CELSR1 | c.8255G>A p.R2752H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.904); catalogued as rs781447851, COSV99418391; called by muse, mutect2, varscan2
- CELSR1 | c.2146G>A p.A716T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); catalogued as rs758640071, COSV53085420; called by muse, mutect2, varscan2
- CELSR1 | c.769A>T p.N257Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99418398; called by muse, varscan2
- CELSR2 | c.3685G>A p.D1229N | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV99603901; called by muse, mutect2, varscan2
- CENPE | c.7542G>C p.V2514= | Splice Region (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99478008; called by muse, mutect2, varscan2
- CENPE | c.3801T>A p.N1267K | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.067); catalogued as COSV99477072, COSV99478009; called by muse, mutect2, varscan2
- CENPI | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99515427; called by muse, mutect2, varscan2
- CENPT | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs779497731, COSV99535108; called by muse, mutect2, varscan2
- CEP112 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67138329; called by muse, mutect2, varscan2
- CEP120 | c.2581-1G>A p.X861_splice | Splice Site (SNP) | VAF 58/198 reads (29%) | catalogued as COSV100071136, COSV60267531; called by muse, mutect2, varscan2
- CEP152 | c.1739A>G p.D580G | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV100358827; called by muse, mutect2, varscan2
- CEP162 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as COSV100002837; called by muse, mutect2, varscan2
- CEP170 | c.1190A>G p.E397G | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100317127; called by muse, mutect2, varscan2
- CEP170B | c.1324G>A p.A442T (on ENST00000453495; = p.A371T on NM_015005.3) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV101371515; called by muse, mutect2, varscan2
- CEP170B | c.2671C>T p.P891S (on ENST00000453495; = p.P820S on NM_015005.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761637315, COSV101371516; called by muse, mutect2, varscan2
- CEP192 | c.3548C>T p.T1183I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1202159653, COSV100381298; called by muse, mutect2, varscan2
- CEP192 | c.7492A>G p.N2498D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV100381300; called by muse, mutect2
- CEP250 | c.3517G>A p.G1173R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs377120249; called by muse, mutect2, varscan2
- CEP290 | c.6772C>T p.L2258F | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV100468788; called by muse, mutect2, varscan2
- CEP290 | c.6318A>T p.E2106D | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100468792; called by muse, mutect2, varscan2
- CEP55 | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101017037; called by muse, mutect2, varscan2
- CEP72 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99374831, COSV99375085; called by muse, mutect2, varscan2
- CEP85L | c.1304C>G p.S435* | Nonsense Mutation (SNP) | VAF 22/108 reads (20%) | catalogued as COSV100821233; called by muse, varscan2
- CEP97 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59128478; called by muse, mutect2, varscan2
- CERK | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.068); catalogued as rs752339759, COSV99348608; called by muse, mutect2, varscan2
- CERT1 | c.1432C>T p.P478S (on ENST00000405807 / NM_001130105.1; = p.P350S on NM_005713.3) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99783303; called by muse, mutect2, varscan2
- CES3 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs763361117, COSV57593631; called by muse, mutect2, varscan2
- CFAP100 | c.1817T>C p.L606P | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as rs752596545, COSV100729239; called by muse, mutect2, varscan2
- CFAP43 | c.4589G>A p.R1530H | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as rs745413621, COSV63853220; called by muse, mutect2, varscan2
- CFAP44 | c.1448A>T p.Y483F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs775091254, COSV55616399; called by muse, varscan2
- CFAP61 | c.2260G>A p.V754I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs758351689, COSV99844985; called by muse, varscan2
- CFAP74 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs754033088, COSV54574836; called by muse, mutect2, varscan2
- CFAP74 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs746426887; called by muse, mutect2, varscan2
- CFAP77 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV100524715; called by muse, mutect2, varscan2
- CFAP97 | c.1472G>A p.R491K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1370444608, COSV101515142; called by muse, mutect2
- CGAS | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV100943673; called by muse, mutect2, varscan2
- CGB1 | c.394del p.R132Afs*? | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs1276406376; called by mutect2, pindel, varscan2
- CHD4 | c.4504C>T p.R1502C (on ENST00000357008 / NM_001363606.2; = p.R1515C on NM_001273.5) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs200017158, COSV58905433; called by muse, mutect2, varscan2
- CHD5 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1477375151, COSV99313708; called by muse, mutect2, varscan2
- CHD6 | c.7685C>T p.T2562M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs375040457; called by muse, mutect2, varscan2
- CHD6 | c.4423A>G p.T1475A | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100951020; called by muse, mutect2, varscan2
- CHD8 | c.1733G>A p.R578H (on ENST00000646647 / NM_001170629.2; = p.R299H on NM_020920.4) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452630110, COSV67869962; called by muse, mutect2, varscan2
- CHERP | c.1291T>A p.W431R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99550265; called by muse, mutect2
- CHL1 | c.3113A>T p.E1038V (on ENST00000397491 / NM_001253387.1; = p.E1054V on NM_006614.4) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV99851287; called by muse, mutect2, varscan2
- CHMP1A | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs767659184, COSV99498312; called by muse, mutect2, varscan2
- CHMP2A | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs144804005; called by muse, mutect2, varscan2
- CHMP4C | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51927156; called by mutect2, varscan2
- CHPF | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99704991; called by muse, mutect2, varscan2
- CHPF | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.354); catalogued as COSV99704993; called by muse, mutect2, varscan2
- CHRDL2 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs376221805; called by muse, mutect2, varscan2
- CHRM2 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV100281339; called by muse, mutect2, varscan2
- CHRNA1 | c.367del p.I123Ffs*67 (on ENST00000261007 / NM_001039523.3; = p.I98Ffs*67 on NM_000079.4) | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | catalogued as rs753250273; called by mutect2, pindel, varscan2
- CHRNA9 | c.1349A>C p.K450T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV100038964; called by muse, mutect2, varscan2
- CHRNB1 | c.1215T>A p.N405K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV100043568; called by muse, mutect2, varscan2
- CHST1 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs563347855, COSV100346247; called by muse, mutect2, varscan2
- CHST10 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 34/111 reads (31%) | catalogued as rs370119165; called by muse, mutect2, varscan2
- CHST2 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58884607, COSV58885088; called by muse, mutect2, varscan2
- CHST6 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM053808, CM122350, COSV100178402; called by muse, mutect2, varscan2
- CHST7 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52100995; called by muse, mutect2, varscan2
- CHST7 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV99332966; called by muse, mutect2
- CHSY1 | c.1963T>A p.Y655N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99573912; called by muse, mutect2, varscan2
- CHTF18 | c.1314C>A p.D438E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99135792; called by muse, mutect2, varscan2
- CHTF18 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as rs774472730, COSV99242959; called by muse, mutect2, varscan2
- CIAO3 | c.1428G>A p.W476* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV52405292; called by muse, mutect2
- CIAPIN1 | c.52A>T p.K18* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101275892; called by muse, mutect2, varscan2
- CIB3 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV99521803; called by muse, mutect2, varscan2
- CIC | c.2932G>A p.V978M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV99359616; called by muse, mutect2, varscan2
- CIITA | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs375045681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CILP | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.111); catalogued as rs991956704, COSV56024511; called by muse, mutect2, varscan2
- CIZ1 | c.1306C>T p.H436Y | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.029); catalogued as COSV99476904; called by muse, mutect2, varscan2
- CKAP5 | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs199835668, COSV56372373; called by muse, mutect2, varscan2
- CLCN6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100411920; called by muse, mutect2, varscan2
- CLCN7 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1395527274, CM1411739, COSV99247292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLDN15 | c.686A>C p.*229Sext*26 | Nonstop Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100385248; called by muse, mutect2, varscan2
- CLDN15 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs374570698, COSV57658972; called by muse, mutect2, varscan2
- CLDN18 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs761116930, COSV51736198, COSV51737856; called by muse, mutect2, varscan2
- CLDN19 | c.222C>T p.D74= | Splice Region (SNP) | VAF 14/34 reads (41%) | catalogued as rs1279756315, COSV99591632; called by muse, mutect2, varscan2
- CLDN2 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 33/59 reads (56%) | catalogued as COSV100390108; called by muse, mutect2, varscan2
- CLEC18B | c.538T>C p.C180R | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100375959; called by muse, mutect2, varscan2
- CLEC3B | c.457G>C p.A153P | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.217); catalogued as COSV56110272, COSV99944558; called by muse, mutect2, varscan2
- CLINT1 | c.1819T>A p.S607T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0.013); catalogued as COSV51629608; called by muse, mutect2, varscan2
- CLINT1 | c.790A>T p.I264F | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV51629623; called by muse, mutect2
- CLIP1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs113784516, COSV100211785; called by muse, mutect2, varscan2
- CLIP2 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs200008575, COSV99791618; called by muse, mutect2, varscan2
- CLIP2 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.193); catalogued as COSV99791620; called by muse, mutect2, varscan2
- CLN3 | c.440C>T p.S147F (on ENST00000360019 / NM_001286104.2; = p.S171F on NM_000086.2) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1401497994, COSV100343091; called by muse, mutect2, varscan2
- CLSTN1 | c.2845G>A p.E949K (on ENST00000377298 / NM_001009566.3; = p.E939K on NM_014944.4) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs1180529851, COSV100740216, COSV100740625; called by muse, mutect2, varscan2
- CLSTN1 | c.2650G>A p.A884T (on ENST00000377298 / NM_001009566.3; = p.A874T on NM_014944.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.725); catalogued as rs757264934, COSV100740217; called by muse, mutect2, varscan2
- CLSTN1 | c.1276C>T p.R426W (on ENST00000377298 / NM_001009566.3; = p.R416W on NM_014944.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs375187320; called by muse, mutect2, varscan2
- CLU | c.657C>G p.F219L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as COSV100324316, COSV57067669; called by muse, mutect2, varscan2
- CMIP | c.635C>T p.S212L (on ENST00000537098 / NM_198390.2; = p.S118L on NM_030629.3) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV101220908; called by muse, mutect2, varscan2
- CMSS1 | c.741G>A p.M247I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs756587102, COSV101375564; called by muse, mutect2, varscan2
- CMTM3 | c.382G>C p.A128P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100726191; called by muse, mutect2, varscan2
- CNKSR1 | c.805G>A p.E269K (on ENST00000374253 / NM_001297647.2; = p.E262K on NM_006314.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100836739; called by muse, varscan2
- CNKSR2 | c.647T>A p.I216N | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99668623; called by muse, mutect2, varscan2
- CNN2 | c.692A>G p.Y231C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs757933615, COSV99565847; called by muse, mutect2, varscan2
- CNOT1 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.026); catalogued as rs1267935014, COSV57781728; called by muse, mutect2, varscan2
- CNOT2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs762668312, COSV57504181; called by muse, mutect2, varscan2
- CNPPD1 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56089124; called by muse, mutect2, varscan2
- CNTN2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1473353987, COSV100085038; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN2 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV100085041; called by muse, mutect2, varscan2
- CNTN3 | c.2470A>G p.N824D | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99724541; called by muse, mutect2, varscan2
- CNTNAP1 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.371); catalogued as COSV99226465; called by mutect2, varscan2
- CNTNAP4 | c.3775G>A p.A1259T | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56703212; called by muse, mutect2, varscan2
- COASY | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as rs200491699; called by muse, mutect2, varscan2
- COG6 | c.433A>G p.K145E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100742924; called by muse, mutect2, varscan2
- COG7 | c.783G>A p.W261* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100207571, COSV56148946; called by muse, mutect2, varscan2
- COL10A1 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV99684255; called by muse, mutect2, varscan2
- COL11A2 | c.3481C>T p.P1161S (on ENST00000341947 / NM_080680.3; = p.P1054S on NM_080679.2) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100554060; called by muse, mutect2, varscan2
- COL16A1 | c.4191G>A p.M1397I | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.276); catalogued as COSV99594535; called by muse, mutect2, varscan2
- COL17A1 | c.2819C>T p.S940L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as rs763104222, COSV100793177; called by muse, mutect2, varscan2
- COL18A1 | c.5009G>A p.R1670H (on ENST00000359759 / NM_130444.3; = p.R1435H on NM_030582.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs757116735, COSV60589336; called by muse, mutect2, varscan2
- COL1A2 | c.2891G>C p.G964A | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99799827; called by muse, mutect2, varscan2
- COL20A1 | c.2246T>C p.L749P | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58928702; called by muse, mutect2, varscan2
- COL21A1 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 52/167 reads (31%) | catalogued as rs1472486062, COSV55182208; called by muse, mutect2, varscan2
- COL24A1 | c.2888G>T p.G963V | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100993368; called by muse, mutect2, varscan2
- COL27A1 | c.62+1del | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | catalogued as rs756877794; called by mutect2, varscan2
- COL2A1 | c.4376G>A p.R1459H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs777416478, COSV99873421; called by muse, mutect2, varscan2
- COL4A2 | c.3385G>A p.D1129N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as rs1438118274, COSV64635243; called by muse, mutect2, varscan2
- COL4A5 | c.3062G>A p.G1021E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100087857, COSV60366881; called by muse, mutect2, varscan2
- COL4A6 | c.3371G>T p.G1124V | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564171; called by muse, mutect2, varscan2
- COL5A1 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as rs148548209, COSV65669151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs758242849, COSV62616343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.8868del p.A2957Lfs*44 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs398102314; called by mutect2, varscan2*
- COL6A3 | c.8866del p.A2956Lfs*45 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as COSV55095179; called by mutect2, varscan2*
- COL6A3 | c.2756C>T p.A919V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs115327470, COSV55089446; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- COL9A2 | c.1242del p.G415Efs*116 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs756694568; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- COL9A3 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100673414; called by muse, mutect2, varscan2
- COLGALT1 | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99395062; called by muse, mutect2
- COLGALT1 | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99395065; called by muse, mutect2, varscan2
- COLGALT2 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs763120148, COSV62298928; called by muse, mutect2, varscan2
- COMMD7 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as rs535513070, COSV99640704; called by muse, mutect2, varscan2
- COPG1 | c.735C>T p.G245= | Splice Region (SNP) | VAF 16/63 reads (25%) | catalogued as COSV59116896; called by muse, mutect2
- COPG1 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1560066141, COSV59116914; called by muse, mutect2, varscan2
- COPS6 | c.592A>T p.I198F | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100384935; called by muse, mutect2, varscan2
- COPS6 | c.722A>T p.Y241F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV100384936; called by muse, mutect2, varscan2
- COQ2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758103492, COSV61022177, COSV61022286; called by muse, mutect2, varscan2
- COQ3 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.241); catalogued as COSV99632736; called by muse, mutect2, varscan2
- COQ6 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV99473941; called by muse, mutect2, varscan2
- COQ9 | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99345812; called by muse, mutect2, varscan2
- CORIN | c.2150G>A p.G717D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs748852470, COSV99903687; called by muse, mutect2, varscan2
- CORO1A | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV54630994; called by muse, mutect2, varscan2
- CPD | c.195G>T p.E65D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99852904; called by muse, mutect2
- CPD | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99852905; called by muse, mutect2
- CPD | c.1940C>A p.P647H | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV99852907; called by muse, mutect2, varscan2
- CPN2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV100103103; called by muse, mutect2, varscan2
- CPNE2 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV99321417; called by muse, mutect2, varscan2
- CPNE4 | c.56A>T p.N19I | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV101456703; called by muse, mutect2, varscan2
- CPNE5 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99782791; called by muse, mutect2, varscan2
- CPNE9 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56008013; called by muse, mutect2, varscan2
- CPNE9 | c.1021A>G p.I341V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.168); catalogued as COSV56070125; called by muse, mutect2, varscan2
- CPO | c.969A>C p.E323D | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV99786511; called by muse, mutect2, varscan2
- CPSF1 | c.4121C>T p.A1374V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100450462; called by muse, mutect2, varscan2
- CPSF6 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99879381; called by muse, mutect2, varscan2
- CPSF7 | c.244G>A p.A82T (on ENST00000394888 / NM_001136040.4; = p.A125T on NM_024811.4) | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.769); catalogued as COSV100467343; called by muse, mutect2, varscan2
- CPT2 | c.1331A>T p.D444V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV99598151; called by muse, mutect2, varscan2
- CPXCR1 | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV52161128; called by muse, varscan2
- CPXM1 | c.1045+1G>A p.X349_splice | Splice Site (SNP) | VAF 38/97 reads (39%) | catalogued as COSV101013739; called by muse, mutect2, varscan2
- CPXM1 | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101013740; called by muse, mutect2, varscan2
- CRACD | c.1107G>A p.W369* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99949328; called by muse, mutect2, varscan2
- CRACDL | c.85A>G p.K29E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67410392; called by muse, mutect2, varscan2
- CRACR2B | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV58991248; called by muse, mutect2, varscan2
- CRB1 | c.1560G>A p.M520I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100957890; called by muse, mutect2, varscan2
- CRB1 | c.2875G>A p.G959S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs557111131, CM043273, COSV66332494; called by muse, mutect2, varscan2
- CRB2 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100749649; called by muse, mutect2, varscan2
- CRB2 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100749652; called by muse, mutect2, varscan2
- CRELD1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs765788326, COSV99926525; called by muse, varscan2
- CRHR2 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as rs764886717, COSV59267348; called by muse, mutect2, varscan2
- CRISPLD1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100082035; called by muse, mutect2, varscan2
- CRTC3 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1426779192, COSV99185685; called by muse, mutect2, varscan2
- CRY1 | c.1361T>A p.I454N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV99150796; called by muse, mutect2, varscan2
- CRY1 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 35/141 reads (25%) | catalogued as COSV99150800, COSV99151025; called by muse, mutect2, varscan2
- CS | c.918G>A p.Q306= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as COSV57526100; called by muse, mutect2, varscan2
- CS | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs140943640; called by muse, mutect2, varscan2
- CSF2RA | c.781-1G>A p.X261_splice | Splice Site (SNP) | VAF 50/716 reads (7%) | catalogued as COSV62627082; called by muse, mutect2
- CSK | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1383516475, COSV99583661; called by muse, mutect2, varscan2
- CSMD1 | c.5123C>T p.T1708M (on ENST00000520002; = p.T1707M on NM_033225.6) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763081825, COSV59371040; called by muse, mutect2, varscan2
- CSMD2 | c.4954C>T p.P1652S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.531); catalogued as COSV99590346; called by muse, mutect2
- CSMD2 | c.4517A>G p.D1506G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99590349; called by muse, mutect2, varscan2
- CSNK1G2 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV99729930; called by muse, mutect2, varscan2
- CSPG4 | c.2639C>T p.P880L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs1305078686, COSV100413794; called by muse, mutect2, varscan2
- CSPG5 | c.1645G>A p.G549S (on ENST00000383738 / NM_001206943.2; = p.G522S on NM_006574.4) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV99273826; called by muse, mutect2, varscan2
- CST3 | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65362395; called by muse, mutect2, varscan2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 14/72 reads (19%) | catalogued as rs767756120; called by mutect2, varscan2
- CTAGE1 | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66945264; called by muse, mutect2, varscan2
- CTC1 | c.3542G>A p.C1181Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV100236087; called by muse, varscan2
- CTC1 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV100236466; called by muse, mutect2, varscan2
- CTC1 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as COSV100236469; called by muse, mutect2, varscan2
- CTCF | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.414); catalogued as rs767996920, COSV50511527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTDNEP1 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.232); catalogued as COSV59709362; called by muse, mutect2, varscan2
- CTNNA1 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs1203968888, COSV100242785; ClinVar: uncertain significance; called by muse, varscan2
- CTNNAL1 | c.224T>A p.V75D | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100336555; called by muse, mutect2, varscan2
- CTR9 | c.2088G>C p.Q696H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100797371; called by muse, mutect2, varscan2
- CTR9 | c.3478G>A p.A1160T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); catalogued as rs1451911867, COSV100797372; called by muse, mutect2, varscan2
- CTTN | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777502801, COSV100097761; called by mutect2, varscan2
- CTTNBP2NL | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99600013; called by muse, mutect2, varscan2
- CUEDC1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64227394; called by muse, mutect2, varscan2
- CUEDC2 | c.818C>G p.A273G | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV50045999, COSV99192723; called by muse, mutect2, varscan2
- CUL2 | c.875del p.N292Mfs*20 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs748548689; called by mutect2, varscan2
- CUL4B | c.1311G>A p.Q437= | Splice Region (SNP) | VAF 98/187 reads (52%) | catalogued as rs1373958825, COSV100340583; called by muse, varscan2
- CUL4B | c.556T>A p.F186I | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100340587; called by muse, mutect2, varscan2
- CUL9 | c.5068G>A p.D1690N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as COSV99335441; called by muse, mutect2, varscan2
- CUL9 | c.7347G>A p.M2449I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs755209921, COSV99335444; called by muse, mutect2, varscan2
- CUX1 | c.1538G>A p.R513Q (on ENST00000437600 / NM_181500.4; = p.R515Q on NM_001913.5) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs1032525805, COSV52922897; called by muse, mutect2, varscan2
- CX3CL1 | c.824T>A p.F275Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV99136352; called by muse, mutect2, varscan2
- CYFIP2 | c.431G>A p.C144Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV59053140; called by muse, mutect2, varscan2
- CYGB | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs369705030, COSV53151299; called by muse, mutect2, varscan2
- CYP20A1 | c.1058T>A p.I353N | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV61910515; called by muse, mutect2, varscan2
- CYP27A1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761927223, COSV51470516; called by muse, mutect2, varscan2
- CYP2C19 | c.168+2T>C p.X56_splice | Splice Site (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100990523; called by muse, mutect2, varscan2
- CYP4A22 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as rs569148380, COSV53742901; called by muse, mutect2, varscan2
- CYSLTR2 | c.776G>A p.C259Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56165728; called by muse, mutect2
- CYTH3 | c.1192A>T p.N398Y (on ENST00000396741; = p.N397Y on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV100084477; called by muse, mutect2, varscan2
- CYTL1 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV57036377; called by muse, varscan2
- DAAM2 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390440173, COSV51417930, COSV51419283; called by muse, mutect2, varscan2
- DAB2IP | c.755A>G p.D252G (on ENST00000408936; = p.D224G on NM_032552.3) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99405529; called by muse, mutect2, varscan2
- DAPK1 | c.2083C>T p.H695Y | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1296783552, COSV100801902; called by muse, mutect2, varscan2
- DAPK3 | c.527A>T p.N176I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100009678; called by muse, mutect2, varscan2
- DAXX | c.1210C>T p.H404Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.158); catalogued as COSV99802142; called by muse, mutect2, varscan2
- DBF4 | c.253T>C p.Y85H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV99719327; called by muse, mutect2, varscan2
- DBN1 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1390363072, COSV52788072; called by muse, mutect2, varscan2
- DCAF15 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.025); catalogued as COSV54337946; called by muse, mutect2, varscan2
- DCAF15 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.155); catalogued as COSV54334007; called by muse, mutect2, varscan2
- DCAF4 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV62319305; called by muse, mutect2, varscan2
- DCAF5 | c.1080G>A p.W360* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100432519; called by muse, mutect2, varscan2
- DCDC1 | c.4879A>G p.I1627V (on ENST00000597505 / NM_001367979.1; = p.I734V on NM_020869.3) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.847); catalogued as rs778477198, COSV58004035; called by muse, mutect2, varscan2
- DCHS1 | c.5017G>T p.A1673S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100202089; called by muse, mutect2, varscan2
- DCN | c.324C>T p.H108= | Splice Region (SNP) | VAF 21/81 reads (26%) | catalogued as rs555086929, COSV99272268, COSV99272565; called by muse, mutect2, varscan2
- DCST1 | c.386A>C p.Y129S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55063961; called by muse, mutect2, varscan2
- DCTN1 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100720962; called by muse, mutect2, varscan2
- DCTN4 | c.35A>T p.Y12F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV101437557; called by muse, mutect2, varscan2
- DCUN1D4 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755838496, COSV58122689; called by muse, mutect2, varscan2
- DDB1 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1195240279, COSV57102223; called by muse, mutect2, varscan2
- DDHD2 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV101240661; called by muse, mutect2, varscan2
- DDIT4L | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 34/112 reads (30%) | catalogued as rs144358521, COSV56767313; called by muse, mutect2, varscan2
- DDR2 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756942296, COSV100906602; called by muse, mutect2, varscan2
- DDRGK1 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs763621314, COSV63227324; called by muse, mutect2, varscan2
- DDX17 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV99318763; called by muse, mutect2, varscan2
- DDX31 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs367667543; called by muse, mutect2, varscan2
- DDX39A | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV54390335; called by muse, mutect2, varscan2
- DDX42 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs767661453, COSV63791187; called by muse, mutect2, varscan2
- DDX43 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100946347; called by muse, mutect2, varscan2
- DDX49 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as COSV99447541; called by muse, mutect2, varscan2
- DDX54 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013902; called by muse, mutect2, varscan2
- DDX54 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs549423905, COSV100013903; called by muse, mutect2, varscan2
4,371 further variants in this file (2,881 protein-altering or splice-affecting, 1,401 silent, 89 other) are not listed here.
